Somatic mutation profile of tumor specimen TARGET-30-PATTDY-01A (aliquot TARGET-30-PATTDY-01A-01D) from TARGET case TARGET-30-PATTDY, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 1.6 years (580 days).
Specimen TARGET-30-PATTDY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcf27bc0-f9f9-401d-bfaf-bd008ec8053c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATTDY-10A (Blood Derived Normal), aliquot TARGET-30-PATTDY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/395d235c-f2ee-4a63-bc95-a4374091999f

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TIAM1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as COSV54578177; called by muse, mutect2
- LRIF1 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- TP53 | c.*1156G>A | 3'UTR (SNP) | VAF 20/169 reads (12%) | catalogued as rs1191845099, COSV104369988; called by muse, mutect2, varscan2
